Somatic mutation profile of tumor specimen TCGA-QT-A5XM-01A (aliquot TCGA-QT-A5XM-01A-11D-A35D-08) from TCGA case TCGA-QT-A5XM, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 43.6 years (15,915 days).
Specimen TCGA-QT-A5XM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d8b860c-9013-4720-8a30-2bf677584f5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A5XM-10A (Blood Derived Normal), aliquot TCGA-QT-A5XM-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e16fb3c-bdb5-4d8e-8f41-a3cad3ecdf16

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RET | c.2753T>C p.M918T | Missense Mutation (SNP) | VAF 42/164 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74799832, CM941246, COSV60685905; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EIF3L | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1310968870, COSV67739875; called by muse, mutect2, varscan2
- ANXA5 | c.813A>C p.R271S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DAZAP2 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 101/363 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GIPC2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- H2BW1 | c.462C>T p.A154= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs139759218; called by muse, mutect2, varscan2
